Gene-level copy-number profile of tumor specimen TCGA-BK-A139-01C from TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.1 years (27,077 days).
Specimen TCGA-BK-A139-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.e844a3bb-b90c-4109-89cd-44fb50d6d175.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A139-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate.
https://portal.gdc.cancer.gov/files/5839d3c1-ba5e-4abe-a756-f5bcab56e51c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 593; copy number 2: 58,499; copy number 3: 1,005; copy number 4: 90; copy number 5: 58; copy number 6: 1; copy number 7: 12; copy number 9: 1; copy number 11: 2; copy number 13: 2; copy number 14: 1; copy number 17: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A139-01A-11D-A275-01): tumor purity 0.44, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:55,777,469–55,777,587, 1 gene: RNA5SP183.
- chr9:5,584,490–5,588,994, 1 gene: AL162253.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 74 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:33,554,636–33,554,859, 1 gene, copy number 14: COX6CP10.
- chr6:33,437,363–33,454,453, 1 gene, copy number 5 (within-gene range 2–5): SYNGAP1-AS1.
- chr6:33,453,970–33,457,544, 1 gene, copy number 5: ZBTB9.
- chr6:158,237,336–158,242,797, 1 gene, copy number 5: SRP72P2.
- chr6:158,296,671–158,303,372, 1 gene, copy number 5: AL360169.3.
- chr7:142,580,917–142,593,473, 3 genes, copy number 5: TRBV12-5, TRBV14, TRBV15.
- chr8:85,107,215–85,146,080, 1 gene, copy number 5 (within-gene range 2–5): LRRCC1.
- chr10:93,893,973–93,956,062, 1 gene, copy number 6 (within-gene range 2–6): SLC35G1.
- chr10:95,109,136–95,111,642, 1 gene, copy number 9: AL157834.1.
- chr13:48,316,863–48,328,564, 2 genes, copy number 11: PPP1R26P1, PCNPP5.
- chr15:25,054,210–25,062,427, 4 genes, copy number 7: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5.
- chr15:25,169,337–25,213,729, 25 genes, copy number 5: DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24.
- chr15:25,239,838–25,257,027, 8 genes, copy number 7: SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr16:1,911,475–2,020,755, 21 genes, copy number 5: HS3ST6, MSRB1, RPL3L, NDUFB10, RPS2, SNORA10, SNORA64, AC005363.1, SNHG9, SNORA78, RNF151, AC005363.2, TBL3, NOXO1, GFER, AC005606.2, SYNGR3, AC005606.1, ZNF598, NPW, RN7SL219P.
- chr20:1,561,385–1,620,061, 2 genes, copy number 13 (within-gene range 2–13): SIRPB1, AL049634.3.
- chr22:25,349,543–25,350,322, 1 gene, copy number 17: AL022324.2.

Autosomal genes at a single copy (total copy number 1): 72. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
